Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5919, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5919-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: STENT, BILE DUCT, REMOVAL –
STENT (gross examination only, see comment).

PART 2: PANCREAS AND DUODENUM, WHIPPLE RESECTION –

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE PANCREATIC HEAD (3.0 CM IN DIAMETER), INVOLVING THE AMPULLA AND COMMON BILE DUCT AND ASSOCIATED WITH ANGIOLYMPHATIC AND PERINEURAL INVASION. PATHOLOGIC STAGE: pT3 N1 Mx.
- B. METASTATIC ADENOCARCINOMA PRESENT IN NINE (9) OF ELEVEN (11) LYMPH NODES. SOFT TISSUE DEPOSITS IDENTIFIED.
- C. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR. HOWEVER, THE TUMOR COMES TO 0.2 CM FROM THE RETROPERITONEAL AND VASCULAR GROOVE MARGINS.

PART 3: LYMPH NODE, RENAL VEIN, BIOPSY –
ONE (1) BENIGN LYMPH NODE.

COMMENT:

Part 1: The specimen labeled "bile duct stent" has been subjected to a gross examination only. If it is desired that this specimen be processed for additional studies, it is suggested that the case pathologist be notified within two weeks of the sign out date of this report. This is particularly important as specimens are routinely discarded after a prescribed period of time.

Part 2: The pancreatic margin shows pancreatic intraepithelial neoplasia (PanIN 1), but is free of carcinoma.

SYNOPTIC DATA - PRIMARY PANCREAS(EXOCRINE) TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
TUMOR SITE: Pancreatic head
TUMOR SIZE: Greatest dimension: 3.0 cm
Additional dimensions: 2.0x2.0 cm

OTHER ORGANS RESECTED: None

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Ductal adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM): pT3
pN1b
Number of lymph nodes examined: 12
Number of lymph nodes involved: 9
pMX
MARGINS: Common bile duct margin uninvolved
Pancreatic parenchymal margin uninvolved
Uncinate process/retroperitoneal margin uninvolved
SMV/portal vein notch margin uninvolved
Proximal duodenal/gastric margin uninvolved
Distal duodenal margin uninvolved
Distance of invasive carcinoma from closest margin: 0.2 mm
Margin: retroperitoneal; vascular groove

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

PERINEURAL INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS: Pancreatic intraepithelial neoplasia (highest grade: PanIN 1)

Source: NCI Genomic Data Commons file 1808b2b7-a71c-4928-b098-8c70c4dc0ca8 (TCGA-FZ-5919.80D1EF4C-4BFF-4733-A636-B0D9AE2E05E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).